TARGET case TARGET-15-SJMPAL012422 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/392a3476-0cb0-4133-b145-d72662e295b3

Demographics
Sex at birth: male; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 7.0 years (2,552 days); Year of diagnosis: 2005; Days to last follow up: 2,071 days (5.7 years).

Follow-up (1 entry)
- Days to follow up: 2,071 days (5.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,071; Year of follow up: 2011.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 150 ×10³/µL.

Biospecimens (5 samples)
- Samples TARGET-15-SJMPAL012422-09A, TARGET-15-SJMPAL012422-09A.1, TARGET-15-SJMPAL012422-09A.2, TARGET-15-SJMPAL012422-09A.3 (4 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL012422-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 2071
- Protocol: St. Jude
- WBC at Diagnosis: 150
- Initial Therapy: AML
- Karyotype: 46,XY,t(11;20)(q10;q10),del(12)(p12)[10]/46,XY[10]
- WHO ALAL Classification: B/M
- WHO Dx: B/M
